TCGA case TCGA-CS-6667 — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Thomas Jefferson University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae081e4a-efa9-4b52-b15e-29085c0612d3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 39 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 39.4 years (14,375 days); Year of diagnosis: 2010; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,469 days (4.0 years); First symptom longest duration: 91-180 Days; First symptom prior to diagnosis: Motor or Movement Changes; Sites of involvement: Brain, Parietal; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 56 days; Course number: 1; Number of fractions: 27; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: Antiseizure Treatment, preoperative; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.

Follow-up (3 entries)
- Day -1 (preoperative): Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 230 days; Disease response: With Tumor.
- Days to follow up: 1,469 days (4.0 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Allergies; Risk factors: Hay Fever / Allergy, Mold or Dust.
- Timepoint category: Prior to Diagnosis; Risk factors: Motor / Movement Change / Sensory Changes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CS-6667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-CS-6667-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-CS-6667-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CS-6667-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Parietal Lobe; History seizures: No; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: Yes; Related symptom first present: Motor/Movement Changes; First symptom longest duration: 91 - 180 Days; History asthma: No; History eczema: No; Histor hay fever: Yes; History dust mold allergy: Yes; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: No; Family history brain tumor: No; Idh1 mutation test indicator: No.
- Follow-up form 1: Treatment outcome first course: Stable Disease; New tumor event diagnosis indicator: No; Tumor status: With tumor.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Stable Disease; Tumor status: With tumor; Treatment outcome at TCGA followup: Stable Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,469 days; disease-specific survival: no event (censored), 1,469 days; progression-free interval: no event (censored), 1,469 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CS-6667-01A-12D-2023-01): tumor purity 0.73, ploidy 2.01, whole-genome doublings 0.
